Somatic mutation profile of tumor specimen TCGA-23-2647-01A (aliquot TCGA-23-2647-01A-01D-1526-09) from TCGA case TCGA-23-2647, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 49.8 years (18,205 days).
Specimen TCGA-23-2647-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09b19910-77c5-42eb-999b-b50b6a5d498e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-2647-10A (Blood Derived Normal), aliquot TCGA-23-2647-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5be08f89-bb82-4731-a7e7-7a206554916f

The open-access MAF lists 70 somatic variants for this specimen: 54 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 14, Frame Shift Del 5, Frame Shift Ins 2, In Frame Del 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTRT1 | c.904G>T p.G302W | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64419166, COSV64419302; called by muse, mutect2, varscan2
- ANO5 | c.1055T>C p.M352T | Missense Mutation (SNP) | VAF 28/762 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs991625488, COSV100202308; called by muse, mutect2
- ARL14EP | c.733C>A p.Q245K | Missense Mutation (SNP) | VAF 16/495 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.329); catalogued as COSV99956110; called by muse, mutect2
- ATF2 | c.877G>C p.D293H | Missense Mutation (SNP) | VAF 143/355 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV51369072, COSV99908458; called by muse, mutect2, varscan2
- ATP6V0A4 | c.703A>T p.I235F | Missense Mutation (SNP) | VAF 58/468 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV59475284; called by muse, mutect2, varscan2
- C16orf72 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 110/311 reads (35%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs374431071; called by muse, mutect2, varscan2
- C3orf20 | c.1722G>C p.K574N | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.159); catalogued as rs144355189, COSV53785730; called by muse, mutect2, varscan2
- CNTNAP2 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1563079216, COSV62175813; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A3 | c.221G>C p.G74A | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV53410186; called by muse, mutect2, varscan2
- COL8A2 | c.2036C>T p.S679L | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs759864363, COSV57441584; called by muse, mutect2, varscan2
- DDX53 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756147094, COSV60068983; called by muse, mutect2, varscan2
- DLGAP1 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 20/281 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as COSV100234418; called by muse, mutect2
- ERICH6 | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 136/189 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV55799291, COSV55800257; called by muse, mutect2, varscan2
- EXOC3L1 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as rs141404625; called by muse, mutect2, varscan2
- FGF23 | c.590C>A p.A197D | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV52975982, COSV52977570; called by muse, mutect2, varscan2
- GFI1 | c.782G>T p.S261I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.486); catalogued as COSV99647675; called by muse, mutect2
- GPC3 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 904/1364 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV63663584; called by muse, mutect2, varscan2
- ICAM5 | c.1543G>C p.V515L | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.68); catalogued as COSV55747150; called by muse, mutect2, varscan2
- INPP5F | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 39/291 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62821157; called by muse, mutect2, varscan2
- KCNC1 | c.468del p.L157Sfs*63 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as COSV56393911; called by mutect2, pindel, varscan2
- LPCAT3 | c.864G>C p.W288C | Missense Mutation (SNP) | VAF 50/367 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54641925; called by muse, mutect2, varscan2
- MDM4 | c.723G>C p.L241F | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV65795545; called by muse, mutect2, varscan2
- MRGPRX3 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 173/411 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV66933589; called by muse, mutect2, varscan2
- NFIA | c.835A>C p.K279Q | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV64534589; called by muse, mutect2
- NLGN4X | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 118/188 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52016108; called by muse, mutect2, varscan2
- NLRP14 | c.3049A>C p.I1017L | Missense Mutation (SNP) | VAF 107/276 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV55066771; called by muse, mutect2, varscan2
- OR4K17 | c.623T>A p.L208Q | Missense Mutation (SNP) | VAF 119/174 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV59647983; called by muse, mutect2, varscan2
- PCDHA2 | c.869A>C p.Q290P | Missense Mutation (SNP) | VAF 95/120 reads (79%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV65366768; called by muse, mutect2, varscan2
- PDLIM2 | c.506G>C p.R169P (on ENST00000397760; = p.R419P on NM_021630.6) | Missense Mutation (SNP) | VAF 62/91 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs775929613, COSV56132594; called by muse, mutect2, varscan2
- PLA2G5 | c.77A>G p.K26R | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.021); catalogued as COSV64282990; called by muse, mutect2, varscan2
- POLE2 | c.625A>C p.S209R | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs1289249590, COSV53559631; called by muse, mutect2, varscan2
- PPP1R3A | c.1946G>A p.S649N | Missense Mutation (SNP) | VAF 97/221 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52878369; called by muse, mutect2, varscan2
- RALY | c.437A>T p.K146M (on ENST00000246194 / NM_016732.3; = p.K130M on NM_007367.4) | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99866284; called by muse, mutect2
- RIPPLY2 | c.139A>C p.K47Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.116); catalogued as COSV63762609; called by muse, mutect2, varscan2
- RUSF1 | c.1262A>G p.K421R | Missense Mutation (SNP) | VAF 112/346 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs755226815, COSV57891357; called by muse, mutect2, varscan2
- SAMD4B | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 72/225 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV58751009; called by muse, mutect2, varscan2
- SEPTIN14 | c.1250A>C p.Q417P | Missense Mutation (SNP) | VAF 95/245 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV66427485; called by muse, mutect2, varscan2
- SEZ6L | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.343); catalogued as COSV50663111; called by muse, mutect2, varscan2
- SLC12A1 | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs537641866, COSV66795746; called by muse, mutect2
- SLC19A2 | c.70C>G p.R24G | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs778987954, CD143916, COSV52547074; called by muse, mutect2, varscan2
- SPANXN1 | c.196C>A p.Q66K | Missense Mutation (SNP) | VAF 212/367 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV65122352; called by muse, mutect2, varscan2
- SYNE1 | c.20256T>A p.D6752E (on ENST00000367255 / NM_182961.4; = p.D6681E on NM_033071.3) | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.115); catalogued as COSV54971603; called by muse, mutect2
- SYNJ1 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 101/252 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV59147804; called by muse, mutect2, varscan2
- TP53 | c.1018_1019insGTGA p.M340Sfs*8 | Frame Shift Ins (INS) | VAF 53/78 reads (68%) | catalogued as COSV53134118; called by mutect2, pindel, varscan2
- TYMP | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 51/91 reads (56%) | SIFT tolerated (0.93); PolyPhen benign (0.022); catalogued as rs367723039; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR7 | c.2467C>T p.R823C | Missense Mutation (SNP) | VAF 93/134 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs745537548, COSV54352491; called by muse, mutect2, varscan2
- ZDHHC18 | c.1117C>G p.P373A | Missense Mutation (SNP) | VAF 107/264 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.551); catalogued as COSV65145328; called by muse, mutect2, varscan2
- ZNF282 | c.545T>G p.V182G | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV50479909; called by muse, mutect2, varscan2
- FBXL13 | c.121dup p.M41Nfs*32 | Frame Shift Ins (INS) | VAF 48/189 reads (25%) | called by mutect2*, pindel, varscan2*
- OR4C13 | c.791_819del p.P264Hfs*24 | Frame Shift Del (DEL) | VAF 70/297 reads (24%) | called by mutect2, pindel, varscan2
- PPM1F | c.1083_1093del p.F362Rfs*82 | Frame Shift Del (DEL) | VAF 18/27 reads (67%) | called by mutect2, pindel, varscan2
- SLC30A3 | c.673del p.L225Cfs*240 | Frame Shift Del (DEL) | VAF 42/137 reads (31%) | called by mutect2, pindel, varscan2
- SZT2 | c.9155_9169del p.R3052_Q3056del (on ENST00000634258 / NM_001365999.1; = p.R2995_Q2999del on NM_015284.4) | In Frame Del (DEL) | VAF 19/192 reads (10%) | called by mutect2, pindel, varscan2
- ZNF25 | c.843_852del p.G282Pfs*97 | Frame Shift Del (DEL) | VAF 82/233 reads (35%) | called by mutect2, pindel, varscan2
- AAMDC | c.93G>T p.G31= | Silent (SNP) | VAF 146/373 reads (39%) | catalogued as COSV59017891; called by muse, mutect2, varscan2
- ANKRA2 | c.348C>G p.T116= | Silent (SNP) | VAF 240/355 reads (68%) | catalogued as COSV57140827; called by muse, mutect2, varscan2
- AP002512.3 | c.759C>G p.V253= | Silent (SNP) | VAF 81/205 reads (40%) | catalogued as COSV54406496; called by muse, mutect2, varscan2
- ATP5MD | c.165G>A p.V55= | Silent (SNP) | VAF 30/443 reads (7%) | catalogued as COSV100428337, COSV100428342; called by muse, mutect2
- FOXM1 | c.1752T>C p.P584= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as COSV61205912; called by muse, mutect2, varscan2
- GMDS | c.750C>G p.G250= | Silent (SNP) | VAF 140/493 reads (28%) | catalogued as COSV66414486; called by muse, mutect2, varscan2
- GPR4 | c.789C>T p.R263= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1310847874, COSV59916890; called by muse, mutect2, varscan2
- IL10RA | c.861A>T p.P287= | Silent (SNP) | VAF 202/516 reads (39%) | catalogued as COSV57140427; called by muse, mutect2, varscan2
- LCE2C | c.174C>A p.P58= | Silent (SNP) | VAF 128/332 reads (39%) | catalogued as COSV64228406; called by muse, mutect2, varscan2
- PDIA4 | c.1344G>A p.E448= (on ENST00000286091 / NM_001371244.1; = p.E447= on NM_004911.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 169/408 reads (41%) | catalogued as rs1444477285, COSV53724604; called by muse, mutect2, varscan2
- PPP1R21 | c.417G>A p.E139= | Silent (SNP) | VAF 11/150 reads (7%) | catalogued as rs1422297788, COSV54286940; called by muse, mutect2
- PRG4 | c.30G>T p.L10= | Silent (SNP) | VAF 116/498 reads (23%) | catalogued as COSV66623767; called by muse, mutect2, varscan2
- UBTF | c.1146C>T p.I382= | Silent (SNP) | VAF 69/104 reads (66%) | catalogued as COSV57185904; called by muse, mutect2, varscan2
- WWTR1 | c.516C>T p.V172= | Silent (SNP) | VAF 285/373 reads (76%) | catalogued as COSV62291255; called by muse, mutect2, varscan2
- RBFOX1 | c.28-185127G>T | Intron (SNP) | VAF 255/671 reads (38%) | catalogued as COSV60957347; called by muse, mutect2, varscan2
- TRMT1L | c.-2C>T | 5'UTR (SNP) | VAF 13/19 reads (68%) | catalogued as rs756827190, COSV100833579; called by muse, varscan2
